Gene-level copy-number profile of tumor specimen C3L-03308-54 from CPTAC case C3L-03308, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 66.0 years (24,097 days).
Specimen C3L-03308-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 32410589-8bac-476e-a225-2cc97cdbe994.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03308-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second AscatNGS file.
https://portal.gdc.cancer.gov/files/09b5f9ed-f04b-43b2-b0a4-e99216824574

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,392; copy number 1: 1,030; copy number 2: 54,560; copy number 3: 279; copy number 4: 14; copy number 5: 14; copy number 6: 16; copy number 7: 57; copy number 8: 6; copy number 9: 1; copy number 10: 4; copy number 11: 4; copy number 12: 4; copy number 16: 1; copy number 17: 2.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,170,733–32,176,568, 1 gene (within-gene range 0–2): AL049795.2.
- chr1:32,286,452–32,333,635, 2 genes: Y_RNA, HDAC1.
- chr1:32,361,270–32,364,278, 1 gene (within-gene range 0–2): FAM229A.
- chr1:32,421,979–32,426,789, 2 genes: AL356986.1, LRRC37A12P.
- chr1:32,465,057–32,605,941, 3 genes (within-gene range 0–1): AL033529.1, ZBTB8B, ZBTB8A.
- chr1:112,820,170–112,877,871, 2 genes: LINC01356, LINC01357.
- chr2:184,902,111–184,902,562, 1 gene (within-gene range 0–1): RPL23AP33.
- chr2:186,162,949–186,163,245, 1 gene: AC104058.1.
- chr3:160,514,907–160,515,236, 1 gene (within-gene range 0–4): SCARNA7.
- chr5:2,921,496–3,181,487, 2 genes: AC094105.2, LINC01377.
- chr6:83,728,055–83,736,525, 1 gene: AL136972.1.
- chr6:84,421,028–84,556,152, 2 genes (within-gene range 0–1): LINC01611, SMARCE1P2.
- chr6:149,963,943–149,973,715, 1 gene: ULBP1.
- chr7:124,929,873–125,933,832, 9 genes (within-gene range 0–2): POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2, AC010099.1, AC010099.2, PPIAP93, AC003975.1.
- chr7:126,868,767–126,870,532, 1 gene (within-gene range 0–1): AC000367.1.
- chr7:129,477,875–129,512,918, 3 genes (within-gene range 0–3): SNRPGP3, RNU1-72P, SMKR1.
- chr7:129,756,266–129,770,492, 2 genes (within-gene range 0–1): RNA5SP244, MIR182.
- chr9:117,276,985–118,072,314, 9 genes (within-gene range 0–2): RN7SKP125, AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1.
- chr11:72,940,498–72,941,112, 1 gene (within-gene range 0–1): AP002381.1.
- chr11:73,214,998–73,242,427, 2 genes (within-gene range 0–1): AP002761.1, P2RY2.
- chr11:73,308,276–73,369,388, 1 gene (within-gene range 0–1): ARHGEF17.
- chr11:73,510,658–73,641,037, 2 genes (within-gene range 0–1): AP000763.2, AP000860.1.
- chr16:25,215,731–25,228,932, 1 gene: AQP8.
- chr16:25,419,812–25,433,686, 1 gene: LINC02191.
- chr16:26,032,539–26,063,097, 2 genes (within-gene range 0–1): HMGN2P3, HSPE1P16.
- chr17:72,290,091–72,640,472, 4 genes (within-gene range 0–1): LINC00511, LINC02003, AC007639.1, RPL32P33.
- chr17:73,067,870–73,068,288, 1 gene (within-gene range 0–1): ATG12P1.
- chr18:41,789,162–41,819,421, 2 genes: NPM1P1, AC011225.1.
- chr19:9,721,903–9,802,301, 7 genes: AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1.
- chr19:9,835,257–9,849,689, 1 gene: PIN1.
- chr20:60,083,360–60,083,872, 1 gene: AL132822.1.
- chr20:61,369,879–61,370,855, 1 gene (within-gene range 0–1): BX640515.1.
- chr22:48,274,364–48,274,415, 1 gene: MIR3201.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 109 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,179,675–32,208,682, 4 genes, copy number 7–16: TXLNA, CCDC28B, AL049795.1, IQCC.
- chr1:32,402,109–32,403,115, 1 gene, copy number 6: GAPDHP20.
- chr1:32,717,734–32,725,237, 1 gene, copy number 5: AC114489.1.
- chr2:185,956,587–185,957,063, 1 gene, copy number 8: RPL21P32.
- chr3:160,404,588–160,404,825, 2 genes, copy number 12 (within-gene range 2–12): MIR15B, MIR16-2.
- chr3:160,753,428–161,078,902, 2 genes, copy number 6–7: AC069224.1, PPM1L.
- chr3:161,104,696–161,253,532, 2 genes, copy number 5 (within-gene range 1–5): NMD3, AC108738.1.
- chr3:161,328,924–161,372,880, 2 genes, copy number 5–10: PSMC1P7, SPTSSB.
- chr3:161,496,808–161,503,942, 1 gene, copy number 7: OTOL1.
- chr5:41,730,065–41,921,636, 5 genes, copy number 5–7: OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51.
- chr6:83,852,312–83,857,515, 2 genes, copy number 17: AL139232.1, RIPPLY2.
- chr6:84,033,772–84,227,643, 2 genes, copy number 6–10: MRAP2, CEP162.
- chr6:84,687,351–84,764,598, 3 genes, copy number 8: TBX18, TBX18-AS1, AL590143.1.
- chr6:149,817,937–149,896,011, 1 gene, copy number 5 (within-gene range 2–12): AL355312.5.
- chr6:149,863,494–149,919,508, 5 genes, copy number 5 (within-gene range 2–14): RAET1E-AS1, CCT7P1, RAET1E, RAET1E-AS1, AL355312.1.
- chr6:149,942,014–149,952,239, 2 genes, copy number 10: ULBP2, AL583835.1.
- chr7:103,297,435–103,370,346, 3 genes, copy number 7 (within-gene range 3–11): PMPCB, DNAJC2, PSMC2.
- chr7:103,352,730–103,446,207, 1 gene, copy number 11 (within-gene range 1–11): SLC26A5.
- chr7:126,378,970–126,424,185, 1 gene, copy number 6: AC000372.1.
- chr10:48,883,955–49,115,522, 6 genes, copy number 6 (within-gene range 2–6): AC060234.3, LRRC18, AC060234.2, AC060234.1, MIR4294, VSTM4.
- chr10:104,031,286–104,126,385, 3 genes, copy number 6–9: COL17A1, MIR936, SFR1.
- chr11:73,376,399–73,397,474, 1 gene, copy number 7 (within-gene range 3–7): RELT.
- chr12:32,100,485–32,107,528, 2 genes, copy number 6 (within-gene range 1–6): AC048344.3, AC048344.1.
- chr14:106,556,936–106,557,477, 1 gene, copy number 7: IGHV3-49.
- chr14:106,583,501–106,583,807, 1 gene, copy number 7 (within-gene range 2–7): IGHV8-51-1.
- chr14:106,592,676–106,879,812, 44 genes, copy number 7: IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr16:26,302,064–26,358,355, 2 genes, copy number 12: AC009158.1, AC130464.1.
- chr17:72,642,731–72,644,490, 1 gene, copy number 5: AC080037.2.
- chr18:41,955,234–42,089,752, 3 genes, copy number 11: PIK3C3, AC087683.2, AC087683.1.
- chr20:60,564,562–60,767,279, 2 genes, copy number 6: MIR548AG2, AL117372.1.
- chr20:61,077,224–61,083,750, 2 genes, copy number 5: AL121910.1, LINC01718.

Autosomal genes at a single copy (total copy number 1): 1,006. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
